Somatic mutation profile of tumor specimen TARGET-10-PARPUL-09A (aliquot TARGET-10-PARPUL-09A-01D) from TARGET case TARGET-10-PARPUL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (820 days).
Specimen TARGET-10-PARPUL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ec1b0d3-cc2f-4363-a5b6-ef2cb2cbb137.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARPUL-10B (Blood Derived Normal), aliquot TARGET-10-PARPUL-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d3d3d68-b230-4b0a-a1de-7d8f69b2ba92

The open-access MAF lists 23 somatic variants for this specimen: 11 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 7, Intron 2, 5'UTR 1, Splice Region 1, In Frame Del 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1514G>A p.R505H (on ENST00000281708 / NM_001349798.2; = p.R425H on NM_018315.5) | Missense Mutation (SNP) | VAF 26/327 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519896, COSV55901126, COSV55908371, COSV55911517; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 94/157 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALDH7A1 | c.1094-3C>T | Splice Region (SNP) | VAF 32/102 reads (31%) | catalogued as rs779179752, COSV63160761; called by muse, mutect2, varscan2
- CBFA2T3 | c.1444G>A p.V482M | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs923460678, COSV51924416, COSV51925172; called by muse, mutect2, varscan2
- FAT4 | c.10579A>C p.T3527P | Missense Mutation (SNP) | VAF 90/168 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58675641; called by muse, mutect2
- MYH6 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1229334328, COSV62448635; called by muse, mutect2, varscan2
- PCDHB3 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50564990; called by muse, mutect2, varscan2
- RPL10 | c.292C>A p.R98S | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV50009981, COSV50010241; called by muse, mutect2, varscan2
- RS1 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1271613655, COSV66106018; called by muse, mutect2, varscan2
- SLITRK5 | c.1575C>A p.F525L | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs549034347, COSV61521576; called by muse, mutect2, varscan2
- NOTCH1 | c.4781_4786del p.R1594_E1595del | In Frame Del (DEL) | VAF 20/75 reads (27%) | called by mutect2, pindel, varscan2
- ERBB2 | c.2049G>T p.R683= | Silent (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- NBEA | c.3804C>T p.D1268= | Silent (SNP) | VAF 11/215 reads (5%) | catalogued as rs949121350, COSV59795817; called by muse, mutect2
- PDZRN4 | c.108C>T p.V36= | Silent (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2
- ROS1 | c.2190G>T p.L730= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV63853597; called by muse, mutect2, varscan2
- SPEN | c.645A>G p.V215= | Silent (SNP) | VAF 5/103 reads (5%) | called by muse, mutect2
- TRIML1 | c.438G>A p.L146= | Silent (SNP) | VAF 50/104 reads (48%) | catalogued as rs1560970086; called by muse, mutect2, varscan2
- TYRO3 | c.2208C>A p.I736= | Silent (SNP) | VAF 18/100 reads (18%) | called by muse, mutect2, varscan2
- KDM4A | c.-35C>T | 5'UTR (SNP) | VAF 31/100 reads (31%) | called by muse, mutect2, varscan2
- LINC00905 | n.1056+49G>A | Intron (SNP) | VAF 23/99 reads (23%) | catalogued as rs879080209; called by muse, mutect2, varscan2
- LINC01545 | n.490C>T | RNA (SNP) | VAF 4/20 reads (20%) | catalogued as rs1466219239; called by muse, mutect2
- TPSD1 | chr16:1262542 G>A | 3'Flank (SNP) | VAF 42/160 reads (26%) | catalogued as rs1054524567; called by muse, mutect2, varscan2
- XKR6 | c.764+62745A>G | Intron (SNP) | VAF 10/254 reads (4%) | catalogued as rs1230444007; called by muse, mutect2
